Somatic mutation profile of tumor specimen TCGA-NF-A5CP-01A (aliquot TCGA-NF-A5CP-01A-12D-A28R-08) from TCGA case TCGA-NF-A5CP, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage IIIC2; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-NF-A5CP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4635a9c-5d69-40f9-a69e-9c40b439e6ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NF-A5CP-10A (Blood Derived Normal), aliquot TCGA-NF-A5CP-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb5b4110-1412-41fd-b2c6-09e0d903eb75

The open-access MAF lists 72 somatic variants for this specimen: 53 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 44, Silent 19, Frame Shift Del 4, Frame Shift Ins 2, In Frame Del 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 60/98 reads (61%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs886042002, CM162636, COSV55873442, COSV55926654, COSV55949642; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.70G>C p.D24H | Missense Mutation (SNP) | VAF 32/80 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs786201995, CM110141, CM993669, COSV64288588, COSV64289716, COSV64295411; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 48/57 reads (84%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS7 | c.1982G>A p.R661Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs764661208; called by muse, varscan2
- AKAP4 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs782072348, COSV100654286; called by muse, mutect2, varscan2
- ASPSCR1 | c.1647G>A p.P549= | Splice Region (SNP) | VAF 11/31 reads (35%) | catalogued as rs780426058; called by muse, mutect2, varscan2
- CASP4 | c.316C>T p.L106F | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as COSV67744850; called by muse, mutect2, varscan2
- CHEK2 | c.1142T>G p.L381R (on ENST00000382580 / NM_001005735.2; = p.L338R on NM_007194.4) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374660293; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DMP1 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 71/88 reads (81%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as rs761098924, COSV99218955; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH11 | c.2619dup p.Y874Ifs*19 | Frame Shift Ins (INS) | VAF 20/63 reads (32%) | catalogued as rs1272994000; called by mutect2, varscan2
- DSP | c.4172A>G p.Y1391C | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs727504547; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EFR3A | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs148528328; called by muse, mutect2, varscan2
- EPG5 | c.1612C>T p.R538W | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs372785168; called by muse, mutect2, varscan2
- LYST | c.3025C>G p.Q1009E | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.051); catalogued as rs1424048559; called by muse, mutect2, varscan2
- MAGEB2 | c.55C>T p.R19* | Nonsense Mutation (SNP) | VAF 20/51 reads (39%) | catalogued as rs773794633, COSV66782156; called by muse, mutect2, varscan2
- MAP1A | c.6473G>A p.R2158Q | Missense Mutation (SNP) | VAF 94/186 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.586); catalogued as rs755004939, COSV55811925; called by muse, mutect2, varscan2
- MED12 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61334558; called by muse, mutect2, varscan2
- NAP1L2 | c.559G>A p.G187S | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV65172467; called by muse, mutect2
- NTRK1 | c.848C>A p.S283Y | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as COSV62325695; called by muse, mutect2, varscan2
- OCEL1 | c.398G>C p.G133A | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.026); catalogued as COSV99285810; called by muse, mutect2
- OR11H12 | c.318del p.N106Kfs*25 | Frame Shift Del (DEL) | VAF 22/80 reads (28%) | catalogued as rs776041024, COSV101612499; called by mutect2, varscan2
- PCDH8 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.069); catalogued as rs754724648, COSV58812519; called by muse, mutect2, varscan2
- PHF1 | c.1528C>T p.R510C | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.116); catalogued as rs368864667; called by muse, mutect2, varscan2
- PHOX2A | c.91G>A p.G31S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV53360103; called by muse, mutect2
- RIMS2 | c.2561C>T p.T854M (on ENST00000666250 / NM_001348490.2; = p.T662M on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749970132, COSV51665339; called by muse, mutect2, varscan2
- SCNN1A | c.610C>G p.R204G | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.93); catalogued as rs759283975; called by muse, mutect2, varscan2
- SEC31A | c.740G>T p.R247L | Missense Mutation (SNP) | VAF 45/59 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV52344382, COSV52345201; called by muse, mutect2, varscan2
- SRRM2 | c.5480G>A p.R1827Q | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs771989272, COSV57079556; called by muse, mutect2, varscan2
- ZFP57 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770753045, COSV65306224; called by muse, mutect2, varscan2
- ZNF470 | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as rs768984736, COSV57969598; called by muse, mutect2, varscan2
- ABCA12 | c.6720G>C p.E2240D (on ENST00000272895 / NM_173076.3; = p.E1922D on NM_015657.3) | Missense Mutation (SNP) | VAF 85/182 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ARHGAP4 | c.2156G>A p.G719E | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- ARID1A | c.1558del p.Q520Sfs*99 | Frame Shift Del (DEL) | VAF 127/432 reads (29%) | called by mutect2, pindel, varscan2
- ARID1A | c.6140_6143dup p.W2048* | Frame Shift Ins (INS) | VAF 41/109 reads (38%) | called by mutect2, pindel, varscan2
- C2 | c.2177G>C p.R726P | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHMP2A | c.258_259del p.S87Pfs*43 | Frame Shift Del (DEL) | VAF 44/181 reads (24%) | called by pindel, varscan2
- DMD | c.8338G>C p.D2780H | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ESX1 | c.542A>T p.D181V | Missense Mutation (SNP) | VAF 69/220 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- FAM124A | c.205C>A p.L69M (on ENST00000322475 / NM_001242312.2; = p.L105M on NM_145019.4) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- FIGN | c.845C>A p.P282H | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- GCK | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- GPR63 | c.836A>T p.Y279F | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- MARCHF7 | c.639_652del p.S214Qfs*30 | Frame Shift Del (DEL) | VAF 10/51 reads (20%) | called by mutect2, pindel, varscan2
- MYO1D | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- P2RY10 | c.426A>T p.R142S | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.101); called by muse, mutect2
- PIK3CA | c.28_49delinsG p.L10_P17delinsA | In Frame Del (DEL) | VAF 46/85 reads (54%) | called by pindel, varscan2*
- RBM26 | c.2694T>G p.F898L (on ENST00000438737 / NM_001366735.2; = p.F871L on NM_022118.5) | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- SBK1 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- TDRD1 | c.2815G>T p.D939Y | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- TREX2 | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 123/396 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- UGGT1 | c.4083G>C p.Q1361H | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VPS13B | c.10436T>G p.I3479S | Missense Mutation (SNP) | VAF 256/290 reads (88%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF571 | c.430T>C p.C144R | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- ACSL4 | c.1270C>T p.L424= (on ENST00000340800 / NM_022977.2; = p.L383= on NM_004458.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/73 reads (49%) | called by muse, mutect2, varscan2
- ARHGAP31 | c.15T>A p.G5= | Silent (SNP) | VAF 10/96 reads (10%) | called by muse, mutect2, varscan2
- CD300C | c.132C>T p.R44= | Silent (SNP) | VAF 31/72 reads (43%) | called by muse, mutect2, varscan2
- DENND2C | c.1866C>T p.Y622= (on ENST00000393274 / NM_001256404.2; = p.Y565= on NM_198459.4) | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as rs769170391; called by muse, mutect2, varscan2
- DGKH | c.1833C>G p.A611= | Silent (SNP) | VAF 23/84 reads (27%) | called by muse, mutect2, varscan2
- FAM161A | c.1137T>C p.Y379= | Silent (SNP) | VAF 51/95 reads (54%) | called by muse, mutect2, varscan2
- GRM3 | c.1722C>T p.D574= | Silent (SNP) | VAF 36/94 reads (38%) | catalogued as rs372193050; called by muse, mutect2, varscan2
- HLA-DQA1 | c.246G>A p.P82= | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as rs1332177306; called by muse, varscan2
- JAM3 | c.96A>G p.V32= | Silent (SNP) | VAF 49/82 reads (60%) | called by muse, mutect2, varscan2
- LRP1 | c.4524C>T p.T1508= | Silent (SNP) | VAF 31/178 reads (17%) | catalogued as rs1297579373, COSV99675106; called by muse, mutect2, varscan2
- MAGEA12 | c.936G>A p.G312= | Silent (SNP) | VAF 85/189 reads (45%) | catalogued as rs1556833703; called by muse, mutect2, varscan2
- MMP21 | c.102G>A p.S34= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs751889257, COSV64289545; called by muse, mutect2, varscan2
- MRPL44 | c.861A>G p.E287= | Silent (SNP) | VAF 43/156 reads (28%) | catalogued as rs750764532; called by muse, mutect2, varscan2
- NOS1 | c.1254G>A p.S418= | Silent (SNP) | VAF 36/95 reads (38%) | catalogued as rs946356254, COSV57608982; called by muse, mutect2, varscan2
- OBSL1 | c.4164C>T p.A1388= | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as COSV54703969; called by muse, mutect2, varscan2
- OR2B11 | c.810C>T p.Y270= | Silent (SNP) | VAF 18/216 reads (8%) | called by muse, mutect2
- POMT1 | c.882C>T p.H294= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as rs191404622, COSV100586587; ClinVar: likely benign; called by muse, mutect2, varscan2
- RP1L1 | c.852G>A p.P284= | Silent (SNP) | VAF 7/81 reads (9%) | catalogued as rs370410297; called by muse, mutect2
- TBC1D4 | c.2508A>G p.S836= | Silent (SNP) | VAF 25/52 reads (48%) | called by muse, mutect2, varscan2
